Somatic mutation profile of tumor specimen C3L-04269-54 (aliquot CPT0410160002) from CPTAC case C3L-04269, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.0 years (25,950 days).
Specimen C3L-04269-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7cdb212-383f-4002-b49c-add03fb98173.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04269-50 (Buccal Cell Normal), aliquot CPT0410130001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10c142d8-75fc-4a43-8a53-dac979f16f0b

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2IRD2B | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 80/769 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs376335386, COSV100441307; called by muse, mutect2, varscan2
- MGA | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV54954230; called by muse, mutect2
- FBXL5 | c.1136T>A p.L379H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- NUP98 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYH2 | c.3384C>T p.I1128= | Silent (SNP) | VAF 77/607 reads (13%) | catalogued as rs139130605; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TRADD | c.151+314T>G | Intron (SNP) | VAF 39/117 reads (33%) | called by muse, varscan2
- UBR3 | c.3634+5872C>T | Intron (SNP) | VAF 25/126 reads (20%) | catalogued as rs571352619; called by muse, mutect2, varscan2
